Somatic mutation profile of tumor specimen TCGA-AK-3453-01A (aliquot TCGA-AK-3453-01A-01W-0886-08) from TCGA case TCGA-AK-3453, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.2 years (21,271 days).
Specimen TCGA-AK-3453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b6249fa-7b43-4228-bbbe-176e298cf80c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3453-10A (Blood Derived Normal), aliquot TCGA-AK-3453-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4139178f-7dc7-406e-9ae7-c902e8aa3ace

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Frame Shift Ins 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 25/138 reads (18%) | catalogued as rs749150409; called by mutect2, varscan2
- MRTFB | c.2530C>T p.P844S (on ENST00000571589 / NM_001365412.2; = p.P794S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs767267381; called by muse, mutect2, varscan2
- OSBPL11 | c.1421G>T p.S474I | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as rs1176549004; called by muse, mutect2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 24/223 reads (11%) | catalogued as rs749506841; called by mutect2, varscan2
- SP1 | c.1340G>T p.G447V (on ENST00000327443 / NM_138473.3; = p.G440V on NM_003109.1) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs376012457; called by muse, mutect2
- ZCCHC17 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.959); catalogued as COSV60004035; called by muse, mutect2
- ARHGAP25 | c.559T>C p.F187L (on ENST00000409202 / NM_001007231.3; = p.F179L on NM_014882.3) | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2
- CATSPERG | c.2326G>C p.G776R | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.123); called by muse, mutect2
- ECSIT | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGD2 | c.977T>G p.V326G | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KMT5B | c.2583A>G p.I861M | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMP3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- OSBPL1A | c.690C>G p.V230= | Splice Region (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- PIAS1 | c.1941T>G p.I647M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- POC1A | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFF3 | c.2781C>T p.G927= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as rs148546971; called by muse, mutect2
- CA13 | c.222A>T p.T74= | Silent (SNP) | VAF 163/413 reads (39%) | called by muse, mutect2, varscan2
- CES3 | c.1368G>A p.V456= | Silent (SNP) | VAF 28/455 reads (6%) | catalogued as rs374347604; called by muse, mutect2
- PAX3 | c.1425G>A p.K475= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- PEX6 | c.669G>T p.V223= | Silent (SNP) | VAF 51/129 reads (40%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.1062G>A p.Q354= | Silent (SNP) | VAF 37/490 reads (8%) | called by muse, mutect2
- SAFB | c.1965G>A p.Q655= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- SPRED3 | c.69C>T p.G23= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs894350313, COSV58312288; called by muse, mutect2
- NXF5 | n.860G>T | RNA (SNP) | VAF 118/279 reads (42%) | called by muse, mutect2, varscan2
